Somatic mutation profile of tumor specimen 0DPU2X from CCDI case PBCEBH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 16.3 years (5,964 days).
Specimen 0DPU2X: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f98a8a1c-d30b-4a30-8f0c-ff30dafec1e5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPU2L (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0f7ac113-3e1e-4953-aa3a-a029be81346a

The open-access MAF lists 58 somatic variants for this specimen: 34 protein-altering or splice-affecting, 14 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 14, Intron 6, Nonsense Mutation 4, 3'UTR 2, Frame Shift Del 1, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.133T>C p.S45P | Missense Mutation (SNP) | VAF 205/386 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs121913407, COSV62687880, COSV62689248, COSV62696859; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABL2 | c.2530A>G p.S844G (on ENST00000502732 / NM_007314.4; = p.S829G on NM_005158.5) | Missense Mutation (SNP) | VAF 39/182 reads (21%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV100772894; called by muse, mutect2, varscan2
- ATG16L1 | c.1600G>A p.G534S (on ENST00000392017 / NM_030803.7; = p.G515S on NM_017974.4) | Missense Mutation (SNP) | VAF 119/357 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs1381021124, COSV100731434; called by muse, mutect2, varscan2
- DNAH8 | c.13470G>T p.K4490N | Missense Mutation (SNP) | VAF 86/552 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1027982582; called by mutect2, varscan2
- DPF3 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 51/387 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs1310485973; called by muse, mutect2, varscan2
- GPR88 | c.754C>T p.H252Y | Missense Mutation (SNP) | VAF 36/178 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.27); catalogued as rs1218004009; called by muse, mutect2, varscan2
- OSBPL2 | c.1411C>T p.R471W (on ENST00000313733 / NM_144498.4; = p.R459W on NM_014835.4) | Missense Mutation (SNP) | VAF 40/264 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374024313; called by muse, mutect2, varscan2
- PAH | c.168G>C p.E56D | Missense Mutation (SNP) | VAF 130/478 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as CM920540; called by muse, mutect2, varscan2
- PRDM9 | c.2641A>T p.T881S | Missense Mutation (SNP) | VAF 166/677 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as rs376492290; called by muse, mutect2, varscan2
- RNF123 | c.2038C>T p.R680* | Nonsense Mutation (SNP) | VAF 157/291 reads (54%) | catalogued as rs1212761475; called by muse, mutect2, varscan2
- RTL9 | c.1549G>A p.A517T | Missense Mutation (SNP) | VAF 26/384 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.017); catalogued as rs746510968; called by muse, mutect2
- SPACA6 | c.917C>G p.S306* | Nonsense Mutation (SNP) | VAF 56/425 reads (13%) | catalogued as rs1425707482; called by muse, mutect2, varscan2
- ZNFX1 | c.1129C>G p.R377G | Missense Mutation (SNP) | VAF 62/570 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65575565; called by muse, mutect2, varscan2
- ACSL6 | c.1989C>G p.F663L (on ENST00000379240; = p.F688L on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/440 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.849); called by muse, mutect2
- ATRX | c.7337T>A p.M2446K | Missense Mutation (SNP) | VAF 18/388 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.439); called by muse, mutect2
- BRI3 | c.76G>T p.G26C | Missense Mutation (SNP) | VAF 78/454 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.714); called by muse, mutect2
- CCNT2 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 64/396 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- CIDEC | c.305C>G p.A102G | Missense Mutation (SNP) | VAF 73/310 reads (24%) | SIFT tolerated (0.6); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- ENTPD4 | c.398T>C p.M133T | Missense Mutation (SNP) | VAF 126/621 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- ESPL1 | c.5601G>C p.E1867D | Missense Mutation (SNP) | VAF 58/414 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- FBN2 | c.4215G>T p.K1405N | Missense Mutation (SNP) | VAF 94/306 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.812); called by mutect2, varscan2
- FREM2 | c.6643C>T p.L2215F | Missense Mutation (SNP) | VAF 117/375 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- GFM1 | c.947_950del p.Y316Sfs*26 | Frame Shift Del (DEL) | VAF 50/398 reads (13%) | called by mutect2, varscan2
- IGSF8 | c.482G>T p.G161V | Missense Mutation (SNP) | VAF 45/243 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- KIR3DL1 | c.128G>T p.G43V | Missense Mutation (SNP) | VAF 68/639 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- LRFN4 | c.427T>A p.F143I | Missense Mutation (SNP) | VAF 17/378 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); called by muse, mutect2
- N4BP3 | c.730C>T p.P244S | Missense Mutation (SNP) | VAF 20/218 reads (9%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.838); called by muse, mutect2
- PRKAG3 | c.789G>T p.E263D | Missense Mutation (SNP) | VAF 95/334 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.688); called by mutect2, varscan2
- PTCHD4 | c.975C>A p.F325L | Missense Mutation (SNP) | VAF 77/469 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- SLC36A4 | c.371C>A p.S124* | Nonsense Mutation (SNP) | VAF 29/139 reads (21%) | called by muse, mutect2, varscan2
- SLC39A12 | c.2019C>G p.I673M (on ENST00000377369 / NM_001145195.2; = p.I636M on NM_152725.3) | Missense Mutation (SNP) | VAF 48/404 reads (12%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- SOWAHD | c.241C>T p.Q81* | Nonsense Mutation (SNP) | VAF 62/529 reads (12%) | called by muse, mutect2, varscan2
- SUPT20H | c.957A>T p.K319N (on ENST00000350612 / NM_001014286.3; = p.K320N on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/411 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.029); called by muse, mutect2
- TADA2B | c.401A>T p.D134V | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- APC | c.1995A>G p.L665= | Silent (SNP) | VAF 70/585 reads (12%) | catalogued as rs1023818848; ClinVar: likely benign; called by muse, mutect2, varscan2
- C5orf34 | c.144A>G p.E48= | Silent (SNP) | VAF 68/532 reads (13%) | catalogued as COSV60930803; called by muse, mutect2, varscan2
- CACNA1B | c.1065C>T p.L355= | Silent (SNP) | VAF 54/592 reads (9%) | catalogued as rs200389919; called by muse, mutect2
- CCDC136 | c.3459G>A p.S1153= | Silent (SNP) | VAF 123/493 reads (25%) | catalogued as rs370532020, COSV52797091; called by muse, mutect2, varscan2
- CDH17 | c.1539C>T p.V513= | Silent (SNP) | VAF 45/389 reads (12%) | catalogued as COSV50325991; called by muse, mutect2, varscan2
- HNRNPA1L2 | c.474C>T p.S158= | Silent (SNP) | VAF 73/613 reads (12%) | catalogued as rs1336457589; called by muse, mutect2, varscan2
- ING3 | c.774T>C p.N258= | Silent (SNP) | VAF 124/426 reads (29%) | catalogued as rs769633520; called by muse, mutect2, varscan2
- NAGPA | c.603G>T p.G201= | Silent (SNP) | VAF 67/449 reads (15%) | called by muse, mutect2, varscan2
- PARP10 | c.843A>T p.G281= | Silent (SNP) | VAF 40/538 reads (7%) | catalogued as rs782517063; called by muse, mutect2
- PRR23A | c.714G>A p.P238= | Silent (SNP) | VAF 43/268 reads (16%) | catalogued as rs753362710; called by muse, mutect2, varscan2
- RELA | c.981A>T p.P327= | Silent (SNP) | VAF 92/676 reads (14%) | called by muse, mutect2, varscan2
- SCARF1 | c.60C>T p.S20= | Silent (SNP) | VAF 61/310 reads (20%) | catalogued as rs751484235, COSV99557164; called by muse, mutect2, varscan2
- SPATA31E1 | c.504A>G p.P168= | Silent (SNP) | VAF 132/488 reads (27%) | called by muse, mutect2, varscan2
- TSPAN19 | c.633T>C p.N211= | Silent (SNP) | VAF 80/303 reads (26%) | catalogued as rs574231127; called by muse, mutect2, varscan2
- AC107023.1 | n.25+5607G>C | Intron (SNP) | VAF 101/432 reads (23%) | called by muse, mutect2, varscan2
- ATP8A1 | c.525-89G>C | Intron (SNP) | VAF 8/30 reads (27%) | called by muse, mutect2
- EHMT1 | c.3259-18C>T | Intron (SNP) | VAF 27/369 reads (7%) | called by muse, mutect2
- H2BC1 | c.-92A>T | 5'UTR (SNP) | VAF 3/23 reads (13%) | called by muse, mutect2
- HSP90AA1 | c.1755+12C>G | Intron (SNP) | VAF 70/250 reads (28%) | called by muse, varscan2
- PCBD2 | c.*3735C>A | 3'UTR (SNP) | VAF 5/48 reads (10%) | catalogued as COSV99254120; called by muse, mutect2, varscan2
- PIGG | c.*51C>T | 3'UTR (SNP) | VAF 16/83 reads (19%) | called by muse, mutect2, varscan2
- PNCK | chrX:153674063 C>T | 5'Flank (SNP) | VAF 47/414 reads (11%) | called by muse, mutect2, varscan2
- POGLUT1 | c.85+70C>A | Intron (SNP) | VAF 14/83 reads (17%) | catalogued as rs765115424; called by muse, mutect2, varscan2
- PUSL1 | c.77+77G>C | Intron (SNP) | VAF 9/66 reads (14%) | called by muse, mutect2, varscan2
